Somatic mutation profile of cancer-model specimen HCM-CSHL-0617-C22-85A (3D Organoid, passage 6; aliquot HCM-CSHL-0617-C22-85A-01D-A85K-36), derived from the primary tumor of HCMI case HCM-CSHL-0617-C22, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 86.3 years (31,521 days).
Specimen HCM-CSHL-0617-C22-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5a0b764-9ec3-489e-96e4-df7fd39aaf92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0617-C22-11A (Solid Tissue Normal), aliquot HCM-CSHL-0617-C22-11A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e19a121-2d8a-46fc-946d-a9f749fc4b38

The open-access MAF lists 81 somatic variants for this specimen: 56 protein-altering or splice-affecting, 21 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 21, Nonsense Mutation 5, Intron 4, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS8 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 377/379 reads (99%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.86); catalogued as rs775371580; called by muse, mutect2, varscan2
- ARSB | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 262/587 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs1353600307; called by muse, varscan2
- ASXL3 | c.3032C>T p.P1011L | Missense Mutation (SNP) | VAF 154/155 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1461875148; called by muse, mutect2, varscan2
- CCDC61 | c.1230A>G p.S410= | Splice Region (SNP) | VAF 40/491 reads (8%) | catalogued as rs1163867208; called by muse, mutect2
- CNTNAP5 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 191/410 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs765263584; called by muse, mutect2, varscan2
- DCC | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 222/222 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749558240, COSV59091020, COSV59105732; called by muse, mutect2, varscan2
- DIP2C | c.4586C>T p.S1529F | Missense Mutation (SNP) | VAF 255/531 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV55177133; called by muse, mutect2, varscan2
- DNAH9 | c.6704T>C p.I2235T | Missense Mutation (SNP) | VAF 140/287 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764641243; called by muse, varscan2
- EPHA2 | c.2114G>T p.R705L | Missense Mutation (SNP) | VAF 246/247 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100626236, COSV100626377; called by muse, mutect2, varscan2
- H1-2 | c.76A>G p.K26E | Missense Mutation (SNP) | VAF 183/610 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs747091108, COSV59192210; called by muse, varscan2
- KEL | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 366/687 reads (53%) | catalogued as COSV62333479; called by muse, mutect2, varscan2
- MYO1C | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 31/758 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs767997586, COSV99055299; called by muse, mutect2
- SCAF4 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV54590453; called by muse, varscan2
- STK32C | c.1126C>A p.R376S | Missense Mutation (SNP) | VAF 169/375 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV53838935; called by muse, mutect2, varscan2
- USP34 | c.10187T>C p.I3396T | Missense Mutation (SNP) | VAF 110/474 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.888); catalogued as rs1183430363; called by muse, mutect2, varscan2
- VPS13B | c.7339G>T p.G2447C | Missense Mutation (SNP) | VAF 335/524 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100663906; called by muse, mutect2, varscan2
- ANKRD31 | c.2944A>G p.I982V | Missense Mutation (SNP) | VAF 223/464 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATG16L1 | c.1643A>C p.Y548S (on ENST00000392017 / NM_030803.7; = p.Y529S on NM_017974.4) | Missense Mutation (SNP) | VAF 221/423 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- BCL11B | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 258/258 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CACNA1A | c.6835A>G p.T2279A | Missense Mutation (SNP) | VAF 28/540 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.316); called by muse, mutect2
- CACNA2D3 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 268/446 reads (60%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.038); called by muse, mutect2
- CCDC110 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 133/294 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.167); called by muse, varscan2
- CCND3 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 84/690 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH8 | c.965C>A p.A322E | Missense Mutation (SNP) | VAF 304/560 reads (54%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDO1 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2
- CFAP221 | c.1757G>T p.R586I | Missense Mutation (SNP) | VAF 209/421 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CFAP47 | c.9445C>A p.H3149N | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLN8 | c.530G>A p.W177* | Nonsense Mutation (SNP) | VAF 227/227 reads (100%) | called by muse, mutect2, varscan2
- DSP | c.2500A>T p.K834* | Nonsense Mutation (SNP) | VAF 193/663 reads (29%) | called by muse, mutect2, varscan2
- FREM1 | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 206/366 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.071); called by muse, varscan2
- HFM1 | c.932T>C p.V311A | Missense Mutation (SNP) | VAF 124/132 reads (94%) | SIFT tolerated (0.14); PolyPhen benign (0.366); called by muse, varscan2
- KCNMB3 | c.460T>G p.C154G | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCTD6 | c.200_201del p.Y67Cfs*17 | Frame Shift Del (DEL) | VAF 166/514 reads (32%) | called by pindel, varscan2
- LEPROTL1 | c.376_378del p.F126del | In Frame Del (DEL) | VAF 91/95 reads (96%) | called by mutect2, pindel, varscan2
- MKRN3 | c.1355G>C p.G452A | Missense Mutation (SNP) | VAF 251/530 reads (47%) | SIFT tolerated (0.87); PolyPhen benign (0.054); called by muse, varscan2
- MYH2 | c.2920A>T p.K974* | Nonsense Mutation (SNP) | VAF 181/411 reads (44%) | called by muse, mutect2, varscan2
- NCKAP5 | c.3878G>T p.G1293V | Missense Mutation (SNP) | VAF 284/622 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFKBID | c.667G>C p.V223L (on ENST00000396901; = p.V375L on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/566 reads (3%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.992); called by muse, mutect2
- OR1L3 | c.465C>A p.H155Q | Missense Mutation (SNP) | VAF 66/418 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- OR52E1 | c.54_55insT p.L19Sfs*33 | Frame Shift Ins (INS) | VAF 164/433 reads (38%) | called by mutect2, pindel, varscan2
- PLIN4 | c.122C>T p.A41V (on ENST00000301286; = p.A56V on NM_001367868.2) | Missense Mutation (SNP) | VAF 260/530 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- POTED | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- PPP4R2 | c.368G>T p.R123I | Missense Mutation (SNP) | VAF 124/239 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- PRRT1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 364/1102 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- SH2D4A | c.1352A>C p.E451A | Missense Mutation (SNP) | VAF 184/184 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SKI | c.11C>A p.A4E | Missense Mutation (SNP) | VAF 70/133 reads (53%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by mutect2, varscan2
- STAT5B | c.39A>C p.E13D | Missense Mutation (SNP) | VAF 157/329 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STK19 | c.782C>A p.T261K (on ENST00000375333 / NM_032454.1; = p.T257K on NM_004197.1) | Missense Mutation (SNP) | VAF 173/548 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- TF | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 264/532 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, varscan2
- TRIM64C | c.664C>A p.H222N | Missense Mutation (SNP) | VAF 26/640 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.581); called by muse, mutect2
- VPS4B | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 166/166 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- YY1AP1 | c.1294A>T p.K432* (on ENST00000295566 / NM_139118.2; = p.K375* on NM_018253.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 52/1156 reads (4%) | called by muse, mutect2
- ZBED9 | c.1174T>C p.F392L | Missense Mutation (SNP) | VAF 141/734 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZFY | c.925T>G p.L309V | Missense Mutation (SNP) | VAF 123/123 reads (100%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- ZNF169 | c.1081C>G p.L361V | Missense Mutation (SNP) | VAF 219/468 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZNF623 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 318/318 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, varscan2
- ACSM2A | c.1479G>C p.V493= (on ENST00000219054; = p.V414= on NM_001308169.2) | Silent (SNP) | VAF 198/618 reads (32%) | called by muse, mutect2, varscan2
- CILP2 | c.2460G>A p.P820= | Silent (SNP) | VAF 142/743 reads (19%) | catalogued as rs1053343182; called by muse, mutect2, varscan2
- CPZ | c.1323G>T p.G441= (on ENST00000360986 / NM_001014447.3; = p.G430= on NM_003652.3) | Silent (SNP) | VAF 139/302 reads (46%) | called by muse, mutect2, varscan2
- CTU1 | c.501C>T p.I167= | Silent (SNP) | VAF 37/542 reads (7%) | catalogued as rs776191804, COSV70292574; called by muse, mutect2
- CYP21A2 | c.471C>T p.T157= | Silent (SNP) | VAF 223/1287 reads (17%) | catalogued as rs1418676297; called by muse, varscan2
- DDX60 | c.4332T>C p.Y1444= | Silent (SNP) | VAF 175/336 reads (52%) | called by muse, mutect2, varscan2
- FAM160A1 | c.603G>T p.L201= | Silent (SNP) | VAF 36/696 reads (5%) | called by muse, mutect2
- HIC2 | c.1509G>A p.R503= | Silent (SNP) | VAF 269/578 reads (47%) | catalogued as rs150684918; called by muse, varscan2
- NISCH | c.1242G>A p.L414= | Silent (SNP) | VAF 172/385 reads (45%) | called by muse, mutect2, varscan2
- PRAMEF18 | c.828G>A p.R276= | Silent (SNP) | VAF 197/454 reads (43%) | called by muse, varscan2
- PTPRH | c.3306C>T p.Y1102= | Silent (SNP) | VAF 45/441 reads (10%) | catalogued as rs763334577, COSV54743976; called by muse, mutect2, varscan2
- RET | c.1210C>T p.L404= | Silent (SNP) | VAF 154/613 reads (25%) | called by muse, mutect2, varscan2
- SOS1 | c.3057A>G p.R1019= | Silent (SNP) | VAF 131/276 reads (47%) | called by muse, mutect2, varscan2
- TENM3 | c.4011C>T p.I1337= | Silent (SNP) | VAF 14/383 reads (4%) | called by muse, mutect2
- UBAP2 | c.1704G>C p.S568= | Silent (SNP) | VAF 147/296 reads (50%) | catalogued as COSV62545015; called by muse, mutect2, varscan2
- UBQLN4 | c.1059G>A p.S353= | Silent (SNP) | VAF 300/1274 reads (24%) | catalogued as rs754532577, COSV64150550; called by muse, varscan2
- VIPR1 | c.351G>A p.P117= | Silent (SNP) | VAF 237/474 reads (50%) | catalogued as rs757213503, COSV57296594; called by muse, varscan2
- WDR72 | c.3261A>T p.P1087= | Silent (SNP) | VAF 177/359 reads (49%) | called by muse, mutect2, varscan2
- ZBTB4 | c.180C>T p.L60= | Silent (SNP) | VAF 392/794 reads (49%) | catalogued as rs763090993; called by muse, mutect2, varscan2
- ZMYM2 | c.4005A>T p.T1335= | Silent (SNP) | VAF 220/221 reads (100%) | called by muse, varscan2
- ZNF729 | c.2832T>C p.A944= | Silent (SNP) | VAF 200/405 reads (49%) | called by muse, mutect2, varscan2
- AL627230.3 | c.75+199C>T | Intron (SNP) | VAF 224/1252 reads (18%) | called by muse, varscan2
- KIR2DL1 | c.715+1454C>A | Intron (SNP) | VAF 22/215 reads (10%) | called by muse, mutect2, varscan2
- NAV3 | c.2024-12928C>A | Intron (SNP) | VAF 196/386 reads (51%) | called by mutect2, varscan2
- PDE4DIP | c.441+1771T>C | Intron (SNP) | VAF 245/540 reads (45%) | called by muse, mutect2, varscan2
